Somatic mutation profile of tumor specimen 0DL6S2 from CCDI case PBBYPM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Germinoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.8 years (3,201 days).
Specimen 0DL6S2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d84b08ac-81da-4111-9d53-1ed26f2d3388.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DL6RH (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e1e41f66-957d-4dac-9602-e7440aa630e8

The open-access MAF lists 7 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Intron 4, Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PPIL2 | c.1502C>T p.A501V | Missense Mutation (SNP) | VAF 131/1230 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs773504375; called by muse, mutect2, varscan2
- GJB6 | c.688A>T p.N230Y | Missense Mutation (SNP) | VAF 163/991 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.019); called by mutect2, varscan2
- CCDC141 | c.1668T>C p.Y556= | Silent (SNP) | VAF 134/903 reads (15%) | called by muse, mutect2, varscan2
- P2RX6 | c.387+77C>A | Intron (SNP) | VAF 12/87 reads (14%) | catalogued as rs982417863; called by mutect2, varscan2
- P2RX6 | c.387+78C>T | Intron (SNP) | VAF 12/86 reads (14%) | catalogued as rs928304917; called by mutect2, varscan2
- SAMD3 | c.822+45A>G | Intron (SNP) | VAF 48/179 reads (27%) | called by muse, mutect2, varscan2
- SLC25A29 | c.79-38C>T | Intron (SNP) | VAF 33/111 reads (30%) | called by muse, mutect2, varscan2
